Somatic mutation profile of tumor specimen C3L-03968-01 (aliquot CPT0228220006) from CPTAC case C3L-03968, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.9 years (22,241 days).
Specimen C3L-03968-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f645fa0-912c-458d-93fb-8fba6c1b51b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03968-31 (Blood Derived Normal), aliquot CPT0228320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48e9a9ef-1a8e-4c0f-8b98-ae3325d8ffae

The open-access MAF lists 108 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 5, Intron 5, RNA 3, Frame Shift Del 2, 5'UTR 2, Splice Site 2, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, mutect2, varscan2
- ALB | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.198); catalogued as rs1483853152; called by muse, mutect2, varscan2
- ARHGEF5 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 109/2454 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746273665; called by muse, mutect2
- BAIAP3 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV60983361; called by muse, mutect2, varscan2
- CABP4 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs771931640, COSV100351399, COSV56887188; called by muse, mutect2, varscan2
- CATSPERD | c.1398G>A p.W466* | Nonsense Mutation (SNP) | VAF 147/274 reads (54%) | catalogued as rs1484343340; called by muse, mutect2, varscan2
- CEMIP2 | c.2255A>G p.D752G | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs779080929; called by muse, mutect2, varscan2
- CHAF1A | c.2092G>C p.G698R | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as rs753505204; called by muse, mutect2, varscan2
- CHRD | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200271; called by muse, mutect2
- DNAH5 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs375292481; called by muse, mutect2, varscan2
- FAM47C | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 100/431 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100792877; called by muse, mutect2, varscan2
- FAM83A | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs758353874, COSV99414628; called by muse, mutect2, varscan2
- GFPT1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs774584997; called by muse, mutect2, varscan2
- GHSR | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 160/842 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1424468940; called by muse, mutect2, varscan2
- IL26 | c.171+2T>C p.X57_splice | Splice Site (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57489666; called by muse, mutect2, varscan2
- JPH1 | c.1204T>G p.C402G | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV60608936; called by muse, mutect2, varscan2
- KCP | c.4025G>A p.R1342H (on ENST00000620378; = p.R1466H on NM_001366122.1) | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs771179921; called by muse, mutect2, varscan2
- LAIR1 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371936514; called by muse, mutect2, varscan2
- LTBP1 | c.3730G>A p.D1244N (on ENST00000404816 / NM_206943.4; = p.D918N on NM_000627.4) | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55383190; called by muse, mutect2
- MAP3K9 | c.2920C>T p.R974C (on ENST00000554752 / NM_001284230.1; = p.R988C on NM_033141.4) | Missense Mutation (SNP) | VAF 93/327 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs780929648, COSV67122173; called by muse, mutect2, varscan2
- ME3 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748084302, COSV62772520; called by muse, mutect2, varscan2
- MPL | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV65245844; called by muse, mutect2, varscan2
- NLRP7 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60178833; called by muse, mutect2
- OCLN | c.422T>G p.M141R | Missense Mutation (SNP) | VAF 119/484 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV62284883; called by muse, mutect2, varscan2
- OR2T33 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58815134; called by muse, mutect2, varscan2
- OR51B2 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1044542503; called by muse, mutect2, varscan2
- OR51G1 | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs775482982, COSV58968393; called by muse, mutect2, varscan2
- RBM19 | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV55692435, COSV99926957; called by muse, mutect2, varscan2
- RIPPLY1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs373247473, COSV104370596; called by muse, mutect2, varscan2
- SLC8B1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs138685380; called by muse, mutect2, varscan2
- TMPRSS11F | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as rs761964521, COSV62465277; called by muse, mutect2, varscan2
- UBTD1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 358/734 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759815921, COSV53968022; called by muse, mutect2, varscan2
- UCHL1 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV52650836; called by muse, mutect2, varscan2
- ADD3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2
- ALX1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARNT2 | c.1564T>G p.Y522D | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ARX | c.1208C>A p.P403Q | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- C10orf90 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- C1orf116 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- C5orf15 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- COL5A3 | c.248-2A>G p.X83_splice | Splice Site (SNP) | VAF 77/115 reads (67%) | called by muse, mutect2, varscan2
- COQ8A | c.1829A>G p.H610R | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDHD2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- DKK2 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLGAP3 | c.572_573del p.G191Efs*5 | Frame Shift Del (DEL) | VAF 89/504 reads (18%) | called by mutect2, pindel, varscan2
- DNAH14 | c.587A>C p.E196A (on ENST00000445597; = p.E19A on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DNASE1L2 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 119/805 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYSF | c.968T>A p.L323H | Missense Mutation (SNP) | VAF 84/446 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EGLN1 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLT3 | c.1830A>T p.L610F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GABRA6 | c.962T>C p.F321S | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA16 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JADE3 | c.1886A>G p.E629G | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC4 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- LRRC27 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MSMP | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.20780C>T p.T6927I | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NDRG4 | c.21+3G>A | Splice Region (SNP) | VAF 55/290 reads (19%) | called by muse, mutect2, varscan2
- NIBAN2 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 92/242 reads (38%) | called by muse, mutect2, varscan2
- NLRP2 | c.517A>T p.K173* | Nonsense Mutation (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- OR11L1 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 98/431 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- OR5AC2 | c.904G>C p.A302P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- PHF11 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PIK3C2B | c.2656del p.A886Pfs*31 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | called by mutect2, pindel, varscan2
- PKD1L3 | c.4T>C p.F2L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by mutect2, varscan2
- PLXNA2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA2 | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PLXNA2 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 111/808 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRDM12 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); called by muse, varscan2
- SLC34A2 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SOX30 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPESP1 | c.68T>A p.I23K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, varscan2
- TTLL5 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- UMOD | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 113/588 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- XPC | c.2687C>A p.A896E | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF677 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- ANKRD30A | c.1917A>C p.P639= (on ENST00000611781; = p.P583= on NM_052997.2) | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- BCL9L | c.717C>T p.F239= | Silent (SNP) | VAF 93/292 reads (32%) | catalogued as rs368576803; called by muse, mutect2, varscan2
- BFSP1 | c.180C>T p.A60= | Silent (SNP) | VAF 117/311 reads (38%) | called by muse, mutect2, varscan2
- CIAO1 | c.564C>T p.A188= | Silent (SNP) | VAF 109/587 reads (19%) | catalogued as rs1042341646; called by muse, mutect2, varscan2
- DRD5 | c.909G>T p.G303= | Silent (SNP) | VAF 59/267 reads (22%) | catalogued as COSV58579073; called by muse, mutect2, varscan2
- EEPD1 | c.1098C>T p.D366= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs765158676; called by muse, mutect2, varscan2
- EN2 | c.465A>G p.E155= | Silent (SNP) | VAF 119/467 reads (25%) | called by muse, mutect2, varscan2
- GZF1 | c.1839G>A p.S613= | Silent (SNP) | VAF 75/403 reads (19%) | catalogued as COSV100582362, COSV57636363; called by muse, mutect2, varscan2
- IGLV4-3 | c.27G>T p.L9= | Silent (SNP) | VAF 35/159 reads (22%) | called by muse, mutect2, varscan2
- KASH5 | c.282G>A p.L94= | Silent (SNP) | VAF 90/316 reads (28%) | called by muse, mutect2, varscan2
- KRT28 | c.765C>T p.L255= | Silent (SNP) | VAF 61/300 reads (20%) | catalogued as rs920919342, COSV60683932; called by muse, mutect2, varscan2
- LATS2 | c.456C>T p.V152= | Silent (SNP) | VAF 85/340 reads (25%) | called by muse, mutect2, varscan2
- LILRB2 | c.531C>T p.S177= | Silent (SNP) | VAF 33/308 reads (11%) | called by muse, varscan2
- MAP7D3 | c.699G>A p.S233= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs770233543, COSV60170216; called by muse, mutect2
- RNF213 | c.9327C>T p.Y3109= | Silent (SNP) | VAF 39/172 reads (23%) | catalogued as rs778158475, COSV60397432; called by muse, mutect2, varscan2
- SI | c.477G>A p.R159= | Silent (SNP) | VAF 55/265 reads (21%) | catalogued as COSV52293269; called by muse, mutect2, varscan2
- SYK | c.837C>T p.S279= | Silent (SNP) | VAF 95/329 reads (29%) | catalogued as COSV101002451; called by muse, varscan2
- TENT4B | c.723G>A p.R241= (on ENST00000561678 / NM_001365323.2; = p.R226= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- TRAV39 | c.273C>T p.T91= | Silent (SNP) | VAF 53/197 reads (27%) | called by muse, mutect2, varscan2
- USP34 | c.10191T>C p.D3397= | Silent (SNP) | VAF 78/369 reads (21%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.723-33T>G | Intron (SNP) | VAF 38/419 reads (9%) | called by muse, mutect2
- DENND10P1 | n.866G>A | RNA (SNP) | VAF 135/557 reads (24%) | called by muse, mutect2, varscan2
- GLRA2 | c.68+1011T>C | Intron (SNP) | VAF 15/84 reads (18%) | catalogued as rs1007783872; called by muse, varscan2
- IRS4 | c.*47C>A | 3'UTR (SNP) | VAF 32/107 reads (30%) | catalogued as COSV64533187; called by muse, mutect2, varscan2
- MAPK9 | c.688+40A>T | Intron (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30364990 G>C | 3'Flank (SNP) | VAF 18/262 reads (7%) | catalogued as rs1234818699; called by muse, mutect2
- MIR9-1 | n.16T>C | RNA (SNP) | VAF 81/215 reads (38%) | called by muse, mutect2, varscan2
- PLXNC1 | c.3252-50G>T | Intron (SNP) | VAF 49/320 reads (15%) | called by muse, mutect2, varscan2
- SLC25A13 | c.-116G>A | 5'UTR (SNP) | VAF 64/288 reads (22%) | called by muse, varscan2
- SPATA31C1 | n.2112C>T | RNA (SNP) | VAF 326/940 reads (35%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3543G>A | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as rs573951969; called by muse, mutect2, varscan2
- TUSC3 | c.-2C>T | 5'UTR (SNP) | VAF 63/300 reads (21%) | called by muse, mutect2, varscan2
